HCMI case HCM-CSHL-0240-C18 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c2e4432f-08a8-46bf-870b-f49cda508c51

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1936; Vital status: Dead; Days to death: 73 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Medullary carcinoma, NOS: ICD-O-3 morphology code: 8510/3; ICD-10 code: C18.5; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Splenic flexure of colon; Classification of tumor: primary; Age at diagnosis: 81.9 years (29,899 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IIIC; AJCC pathologic T: T4b; AJCC pathologic N: N1b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Perineural invasion present: No; Vascular invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 22 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 64 days; Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 37.

Molecular and laboratory tests
- MLH1 (IHC): Positive.
- MSH2 (IHC): Negative.
- MSH6 (IHC): Negative.
- PMS2 (IHC): Positive.
- Test (IHC): Positive; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps / Diabetes, Type II.
- Timepoint category: Initial Diagnosis; Weight: 59.9 kg; Height: 165.1 cm; BMI: 22.

Exposures
- Tobacco smoking status: Current Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0240-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0240-C18-01A-01-S1-HE: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 15; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 6.
  Slide HCM-CSHL-0240-C18-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 55; Percent tumor nuclei: 55; Percent normal cells: 0; Percent necrosis: 25; Percent stromal cells: 20; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 5.
- Sample HCM-CSHL-0240-C18-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0240-C18-11A-01-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 70; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 7; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 9.
  Slide HCM-CSHL-0240-C18-11A-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 12.
- Sample HCM-CSHL-0240-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
